Somatic mutation profile of tumor specimen C3L-03496-54 (aliquot CPT0230700002) from CPTAC case C3L-03496, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 75.8 years (27,693 days).
Specimen C3L-03496-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e8aedcc-ae48-4154-9e92-10428a132394.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03496-51 (Buccal Cell Normal), aliquot CPT0230800001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4cc6c9b-a700-4305-9b9d-9d3a6bf653bf

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Frame Shift Ins 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 25/75 reads (33%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5408C>G p.T1803S | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.197); catalogued as COSV66464823; called by muse, mutect2, varscan2
- CDC14C | c.347C>T p.P116L (on ENST00000428251; = p.P9L on NM_152627.3) | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1213774009; called by muse, mutect2, varscan2
- SLK | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1256904405; called by muse, mutect2, varscan2
- AC011448.1 | c.323del p.P108Rfs*55 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- DSEL | c.3131G>T p.R1044L | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- FGD1 | c.1345C>T p.R449C | Missense Mutation (SNP) | VAF 142/330 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF287 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMP3 | c.1215G>A p.E405= | Silent (SNP) | VAF 67/131 reads (51%) | called by muse, mutect2, varscan2
- CFAP69 | c.2189-16A>G | Intron (SNP) | VAF 48/137 reads (35%) | called by muse, varscan2
- YWHAH | c.87+2624G>A | Intron (SNP) | VAF 69/139 reads (50%) | called by muse, mutect2, varscan2
